CCDI case PBCAFX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/7651b351-98b9-4f6b-b8c8-3f2a2b16baa2

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Overlapping lesion of brain and central nervous system; Age at diagnosis: 2.8 years (1,034 days).

Biospecimens (3 samples)
- Sample 0DMIO0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMIOH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DMIPH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
